Somatic mutation profile of tumor specimen C3N-02757-01 (aliquot CPT0183940007) from CPTAC case C3N-02757, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.8 years (25,121 days).
Specimen C3N-02757-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5800e804-d0a3-40a2-8c73-211265409a4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02757-71 (Blood Derived Normal), aliquot CPT0184000002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14f14e66-7018-49ce-a3ff-cd7afd38c855

The open-access MAF lists 59 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 9, Intron 5, 3'UTR 2, Splice Site 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 198/705 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BRICD5 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs149312425; called by muse, mutect2, varscan2
- CHST3 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 39/369 reads (11%) | catalogued as COSV64150860; called by muse, mutect2, varscan2
- CRIP2 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 31/462 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs782087383, COSV61274934; called by muse, mutect2
- FAXC | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as rs1486511488; called by muse, mutect2, varscan2
- KLHL14 | c.290A>C p.Q97P | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs747083891; called by muse, mutect2, varscan2
- NSD1 | c.3613G>C p.E1205Q | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.203); catalogued as COSV61771053; called by muse, mutect2
- SIRPG | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 25/453 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53806943; called by muse, mutect2
- SNX29 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs201192074; called by muse, mutect2
- ZBTB46 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.642); catalogued as rs1160750317; called by muse, mutect2, varscan2
- ALMS1 | c.7570G>A p.D2524N | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ARFGEF3 | c.4674C>G p.I1558M | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ARSB | c.314T>A p.I105N | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C6orf132 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.462); called by muse, mutect2
- CCDC171 | c.1534C>G p.H512D | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, varscan2
- CYBA | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 32/696 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.253); called by muse, mutect2
- DDX53 | c.797C>A p.A266E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EFCAB5 | c.3352G>A p.V1118I | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.95); called by muse, mutect2
- FAXC | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FOXP2 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, varscan2
- GCN1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- GP9 | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 113/434 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HTR7 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- JAML | c.773C>T p.T258I (on ENST00000356289 / NM_001098526.2; = p.T248I on NM_153206.3) | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- KCNT1 | c.1803C>A p.D601E (on ENST00000488444; = p.D620E on NM_020822.3) | Missense Mutation (SNP) | VAF 90/302 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LRGUK | c.1353A>T p.R451S | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MBOAT7 | c.925T>A p.F309I | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2
- OR5T1 | c.145T>C p.F49L | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCNX3 | c.3674A>G p.Y1225C | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PKMYT1 | c.66T>A p.S22R | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PRKCA | c.1454G>A p.C485Y | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM10 | c.2291G>A p.C764Y | Missense Mutation (SNP) | VAF 124/288 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCARF2 | c.218del p.D73Afs*21 | Frame Shift Del (DEL) | VAF 128/626 reads (20%) | called by pindel, varscan2
- SLC25A12 | c.1224+2T>C p.X408_splice | Splice Site (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2, varscan2
- SLC35G4 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- TJP2 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 13/428 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNRC18 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRMT2A | c.1301G>A p.S434N | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2
- TTC21A | c.820C>G p.Q274E | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- VSTM2A | c.455G>T p.S152I | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2
- VWA8 | c.2753C>T p.T918I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ZNF540 | c.878A>G p.H293R | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- CNOT1 | c.6066A>G p.T2022= | Silent (SNP) | VAF 85/266 reads (32%) | catalogued as rs1211578963; called by muse, mutect2, varscan2
- CYP2A6 | c.1041C>T p.A347= | Silent (SNP) | VAF 21/298 reads (7%) | called by muse, mutect2
- GPIHBP1 | c.210C>T p.S70= | Silent (SNP) | VAF 49/410 reads (12%) | catalogued as rs1324900036, COSV58209421; called by muse, mutect2, varscan2
- GSG1L | c.291C>T p.L97= | Silent (SNP) | VAF 94/505 reads (19%) | called by muse, varscan2
- LCE1F | c.153C>T p.C51= | Silent (SNP) | VAF 44/772 reads (6%) | called by muse, mutect2
- MIA2 | c.681A>G p.Q227= | Silent (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2
- RRP12 | c.222C>G p.A74= | Silent (SNP) | VAF 73/456 reads (16%) | called by muse, mutect2, varscan2
- SYNPO | c.1848C>T p.A616= (on ENST00000394243 / NM_001166208.2; = p.A372= on NM_007286.6) | Silent (SNP) | VAF 12/219 reads (5%) | called by muse, mutect2
- ZNF883 | c.903G>T p.L301= | Silent (SNP) | VAF 10/205 reads (5%) | catalogued as COSV71309152; called by muse, mutect2
- ABHD14A | c.397+20T>A | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- ABLIM3 | c.*1200C>T | 3'UTR (SNP) | VAF 12/170 reads (7%) | catalogued as rs200336012; called by muse, mutect2
- CSMD1 | c.6245-10248G>T | Intron (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.-493+10430C>G | Intron (SNP) | VAF 72/244 reads (30%) | called by muse, mutect2, varscan2
- NCAM1 | c.2131+2526C>A | Intron (SNP) | VAF 6/132 reads (5%) | catalogued as rs782387047; called by muse, mutect2
- TRBV25OR9-2 | n.278T>A | RNA (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- TRIOBP | c.5322+5336C>T | Intron (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- UMPS | c.*3546G>A | 3'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
